Gene-level copy-number profile of tumor specimen TCGA-KQ-A41O-01A from TCGA case TCGA-KQ-A41O, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 84.3 years (30,774 days).
Specimen TCGA-KQ-A41O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.f35ec892-4e22-464f-8916-6a5049de14cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KQ-A41O-10D (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e3f0df38-fbb9-4fcc-b1e1-a4d766d6b62a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 743; copy number 2: 8,912; copy number 3: 12,026; copy number 4: 23,488; copy number 5: 9,012; copy number 6: 4,077; copy number 7: 509; copy number 9: 732; copy number 10: 125; copy number 11: 111; copy number 17: 7; copy number 22: 9; copy number 43: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KQ-A41O-01A-12D-A34T-01): tumor purity 0.93, ploidy 3.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–2): FOCAD.
- chr9:20,716,105–22,824,213, 59 genes: MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 990 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 9 (broad region; genes not listed).
- chr5:53,560,633–54,737,057, 17 genes, copy number 10–22 (within-gene range 2–22): NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1, AC016583.2.
- chr5:54,857,272–55,425,579, 22 genes, copy number 9 (within-gene range 2–9): AC112198.1, AC112198.3, AC112198.2, ESM1, AC034238.1, GZMK, Y_RNA, AC034238.3, AC034238.2, GZMAP1, GZMA, CDC20B, GPX8, MIR449A, MIR449B, MIR449C, MCIDAS, CCNO, AC026704.1, DHX29, MTREX, AC020728.1.
- chr5:60,866,454–60,945,073, 3 genes, copy number 10: ERCC8, GNL3LP1, ERCC8-AS1.
- chr11:62,908,679–63,015,841, 6 genes, copy number 10: CHRM1, AP000438.1, RN7SL259P, SLC22A6, AP000438.2, SLC22A8.
- chr11:65,014,160–65,921,563, 86 genes, copy number 11 (broad region; genes not listed).
- chr11:68,754,620–72,843,674, 146 genes, copy number 10–43 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 743. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
